Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8XX, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8XX-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Accession Number: Report Status: Final
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date:
Ordering Provider:

CASE:

PATIENT: [REDACTED]

Resident:

Pathologist:

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "TUMOR, RIGHT RENAL VEIN AND RIGHT KIDNEY":

LEIOMYOSARCOMA (7.0 cm), high grade.

Mitoses number up to 22:10 HPF.

Necrosis is present.

The vena caval resection margin is negative for tumor.

Tumor is 0.5 cm from the vena caval margin.

One lymph node negative for tumor (0:1).

Kidney with simple cyst, negative for tumor.

ICD-O 3
Leiomyosarcoma 8890/3
Site: Retroperitoneal
848.0
JW 5/5/14

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

RIGHT KIDNEY, NEPHRECTOMY:

MILD CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, MOST LIKELY AGE-RELATED:

- FOCAL GLOBAL GLOMERULOSCLEROSIS (5.6% OF GLOMERULI)
- FOCAL TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS, WITH AN ISOLATED SUBCAPSULAR SCAR (5-10% OF THE PARENCHYMA)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE (SEE NOTE)

NOTE:

The kidney parenchyma sample examined shows minimal chronic changes, within the expected range for a year-old man, and moderate vascular sclerosis.

The kidney parenchyma was evaluated by , Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A9) were evaluated using H&E, PAS, Jones' silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 322 glomeruli present, of which 11 are globally sclerosed. There is a subcapsular scar with 8 additional glomeruli showing global sclerosis (5.6% global sclerosis). The remaining glomeruli show no significant expansion of the mesangial areas. There are no discernible craters or double contours of the glomerular capillary wall basement membranes. In the cortical area, there are two small cysts, with proliferated but benign epithelium. There is focal infiltration by foam cells and deposition of calcium phosphate crystals. Rare distal tubules contain PAS-positive hyaline casts. Less than 10% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries exhibit prominent sclerosis of the wall with focal accumulation of subintimal connective tissue.

END OF RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA

CLINICAL DATA:

History: yo male with R retroperitoneal sarcoma.

Operation: Resection right retroperitoneal mass, R nephro-adrenalectomy.

Operative Findings: Not provided.

Clinical Diagnosis: Sarcoma.

TISSUE SUBMITTED:

A. Tumor rt renal vein and rt kidney - FS

[page 2 of 2]
Sex:M

Pathology Report

GROSS DESCRIPTION:

Part A, the specimen is received fresh, labeled with the patient's name, unit number, and "#1. Rt renal vein and Rt kidney", consists of a radical nephrectomy specimen (1428 g, 30.0 x 18.0 x 6.8 cm) including a right kidney (12.2 x 6.2 x 3.5 cm) surrounded by a thick layer of adipose tissue (no Gerota's fascia), ureter (10.0 cm in length x 0.4 cm in diameter) and renal artery (0.7 cm in length x 0.4 cm in diameter). A thin-walled, unilocular cyst (2.0 cm) filled with clear serous fluid is located in the upper pole. The kidney cortex measures 0.6-1.1 cm in thickness. The kidney parenchyma is brown/tan and otherwise unremarkable. The area designated by the surgeon as abutting the resected mass is inked blue. A white/tan, lobulated, focally hemorrhagic mass (95 g, 7.0 x 6.7 x 4.8 cm) with a thin capsule is separately received. It surrounds a bifurcating vessel (1.4 x 2.5 cm) that is designated by the surgeon as vena cava and the only true margin. The mass is 0.5 cm from the vena caval resection margin. Necrosis is not identified. Gross photographs of the mass are taken. Representative sections of the mass are submitted for electron microscopy, cytogenetics, tissue banking and quick fix. Representative sections of normal kidney are submitted for EM, IF and tissue banking. No adrenal gland is identified. No lymph nodes are identified.

Micro A1: Vena caval margin (en face), 1 frag,
Micro A2: Ureter and artery margins (en face), 2 frags,
Micro A3: Tumor quick fix, 2 frags,
Micro A4-A6: Mass to include areas of hemorrhage and relationship to surrounding fibroadipose tissue and vessel, 1-2 frags each,
Micro A7: Region of nephrectomy specimen abutting mass, multi frags,
Micro A8: Renal simple cyst, 4 frags,
Micro A9: Uninvolved kidney cortex, 1 frag,

CASE NUMBER:

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by

, Electronically signed on

Source: NCI Genomic Data Commons file 7d0f75f3-375d-4aa1-9157-d7a2bfabf1e7 (TCGA-WK-A8XX.F1951562-FFB7-4F7A-8908-4BF43093A88D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).